Somatic mutation profile of tumor specimen TCGA-09-0364-01A (aliquot TCGA-09-0364-01A-02W-0371-08) from TCGA case TCGA-09-0364, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 80.1 years (29,262 days).
Specimen TCGA-09-0364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02735926-1150-4f29-bc6c-3174ac7a0e09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-0364-10A (Blood Derived Normal), aliquot TCGA-09-0364-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc95f908-60d7-4f89-b8b2-9dd1e040a74b

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.1353dup p.N452Qfs*6 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by pindel, varscan2
- TP53 | c.685_696del p.C229_I232del | In Frame Del (DEL) | VAF 26/34 reads (76%) | called by mutect2, pindel, varscan2
- TRIP12 | c.178dup p.T60Nfs*6 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by pindel, varscan2
